TCGA case TCGA-IB-7651 — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: Alberta Health Services. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3559f697-8fec-4f36-962c-632272fe9c9c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 64 years; Vital status: Dead; Days to death: 603 days (1.7 years); Cause of death: Cancer Related; Cause of death source: Medical Record.

Diagnoses (3)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.0; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 64.6 years (23,580 days); Year of diagnosis: 2009; Method of diagnosis: Cytology; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 603 days (1.7 years); Sites of involvement: Pancreas Head.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 3; Lymph nodes tested: 8; Tumor largest dimension diameter: 2.9 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 124 days; Days to treatment end: 343 days; Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Oxaliplatin; Days to treatment start: 581 days (1.6 years); Days to treatment end: 581 days (1.6 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Days to treatment start: 581 days (1.6 years); Days to treatment end: 581 days (1.6 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Whipple.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Infiltrating duct carcinoma, NOS). Age at diagnosis: 65.9 years (24,072 days); Days to diagnosis: 492 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
3. Recurrence of diagnosis 1 (Infiltrating duct carcinoma, NOS). Age at diagnosis: 66.1 years (24,161 days); Days to diagnosis: 581 days (1.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 492 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 492 days (1.3 years); Evidence of recurrence type: Convincing Image Source.
- Day 581 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 581 days (1.6 years).
- Days to follow up: 603 days (1.7 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Diabetes, NOS; Days to comorbidity: 504 days (1.4 years); Days to risk factor: 504 days (1.4 years); Risk factors: Diabetes, NOS.

Exposures
- Alcohol history: Yes; Alcohol intensity: Drinker; Alcohol days per week: 3.
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 20; Tobacco smoking onset year: 1989.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IB-7651-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.5; Shortest dimension: 0.3.
  Slide TCGA-IB-7651-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 65; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 5.
  Slide TCGA-IB-7651-01A-01-TS1: Section location: Top; Percent tumor cells: 99; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-IB-7651-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-IB-7651-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid); Lymph nodes examined: Yes; Tumor status: With tumor; Cause of death: Pancreatic Cancer; Tobacco smoking history indicator: 2; Alcohol exposure intensity: Weekly Drinker; Alcohol consumption frequency: 3; Diabetes diagnosis indicator: Yes; History chronic pancreatitis: No; Treatment outcome first course: Complete Remission/Response.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; Cause of death: Pancreatic Cancer.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Drug treatment 4: Pharmaceutical therapy drug name: 5-Fluorouracil; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 603 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 603 days; disease-free interval: event (new tumor event after initially disease-free), 492 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 492 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-IB-7651-01A-11D-2153-01): tumor purity 0.39, ploidy 2.09, whole-genome doublings 0.
